Somatic mutation profile of tumor specimen ASCProject_0038_T1_WES (aliquot ASCProject_0038_T1_WES_1) from CMI case ASCProject_0038, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 63.1 years (23,035 days).
Specimen ASCProject_0038_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Scalp; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 182d4bc4-a051-442d-b23b-748c01f9368e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0038_SALIVA (Saliva), aliquot ASCProject_0038_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02ce9b96-cc57-4395-b4b6-5bf748825e6d

The open-access MAF lists 85 somatic variants for this specimen: 46 protein-altering or splice-affecting, 21 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 21, Intron 7, 3'UTR 5, RNA 4, Splice Site 2, Nonsense Mutation 2, Splice Region 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM32 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs957652162, COSV65950171; called by muse, mutect2
- ATP13A1 | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52290018; called by muse, mutect2
- COX18 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 22/719 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs1277107478; called by muse, mutect2
- CRB1 | c.2677-1G>A p.X893_splice | Splice Site (SNP) | VAF 32/424 reads (8%) | catalogued as COSV66331077; called by muse, mutect2
- DNAI2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 104/1152 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs538543314; ClinVar: uncertain significance; called by muse, mutect2
- FLT4 | c.2732A>G p.N911S | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372072725; called by muse, mutect2, varscan2
- FNDC4 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as rs1407644913; called by muse, mutect2
- KNG1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV53976673; called by muse, mutect2
- KRT6B | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 46/1346 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52886977; called by muse, mutect2
- M1AP | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759890032, COSV51845043; called by muse, mutect2
- MAB21L1 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59806125; called by muse, mutect2
- MTSS1 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534128090; called by muse, mutect2
- MUC12 | c.15397G>A p.E5133K (on ENST00000379442; = p.E4990K on NM_001164462.1) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); catalogued as COSV65196773; called by muse, mutect2
- PPP4R4 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58555147; called by muse, mutect2
- PTCHD4 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs1324828405, COSV59796708; called by muse, mutect2
- RAG1 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 25/567 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs866525367, BM1314768, COSV55027616; called by muse, mutect2
- STK10 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 41/441 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51573654; called by muse, mutect2, varscan2
- TEKT4 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 28/667 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV54626766; called by muse, mutect2
- THSD7B | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 17/466 reads (4%) | catalogued as COSV99756634; called by muse, mutect2
- WDR81 | c.3238C>T p.P1080S (on ENST00000409644 / NM_001163809.2; = p.P29S on NM_152348.4) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs753798569, COSV100488743; called by muse, mutect2
- ABCG8 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 48/937 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- ADAMTSL2 | c.234G>A p.R78= | Splice Region (SNP) | VAF 28/580 reads (5%) | called by muse, mutect2
- ARAP2 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- CCDC89 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CNTN5 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CREB5 | c.1082C>T p.P361L (on ENST00000357727 / NM_182898.4; = p.P354L on NM_004904.3) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- EML5 | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2
- EPHB6 | c.1415C>G p.P472R | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.522); called by muse, mutect2
- GLRA4 | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2
- HOOK3 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.331); called by muse, mutect2
- KCNT1 | c.1391C>T p.P464L (on ENST00000488444; = p.P483L on NM_020822.3) | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- KMT2C | c.10793C>T p.P3598L | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KPNA6 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- MAGEB3 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.979); called by muse, mutect2
- MATN2 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- NT5E | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.037); called by muse, mutect2
- OPRM1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- OPRM1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2
- PELI2 | c.408A>G p.I136M | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRX | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- RCC1 | c.818-1G>A p.X273_splice | Splice Site (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- SLC9C2 | c.2901T>G p.S967R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- SOX9 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TAF2 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- USP6 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 38/752 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); called by muse, mutect2
- ZSCAN29 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.026); called by muse, mutect2
- ANK2 | c.1356G>A p.Q452= | Silent (SNP) | VAF 26/447 reads (6%) | called by muse, mutect2
- ARFGEF3 | c.3573G>A p.R1191= | Silent (SNP) | VAF 28/478 reads (6%) | catalogued as COSV52451594, COSV52452660; called by muse, mutect2
- ASTL | c.1134C>T p.A378= | Silent (SNP) | VAF 19/358 reads (5%) | called by muse, mutect2
- CCDC89 | c.360G>A p.R120= | Silent (SNP) | VAF 17/406 reads (4%) | called by muse, mutect2
- DUOXA2 | c.456C>T p.D152= | Silent (SNP) | VAF 40/569 reads (7%) | called by muse, mutect2
- FDPS | c.975C>G p.G325= | Silent (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- FGFBP3 | c.24G>A p.A8= | Silent (SNP) | VAF 26/634 reads (4%) | catalogued as rs1211282436; called by muse, mutect2
- HNF4A | c.633C>T p.L211= | Silent (SNP) | VAF 28/500 reads (6%) | called by muse, mutect2
- KBTBD3 | c.1461T>G p.S487= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV73241384; called by muse, mutect2
- KCNC2 | c.261C>T p.S87= | Silent (SNP) | VAF 19/286 reads (7%) | called by muse, mutect2
- KIAA2012 | c.645C>T p.F215= | Silent (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- KRT6C | c.963C>T p.S321= | Silent (SNP) | VAF 30/558 reads (5%) | catalogued as rs1227085179; called by muse, mutect2
- MLXIP | c.1947C>T p.F649= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- MPZL2 | c.327T>G p.L109= | Silent (SNP) | VAF 18/373 reads (5%) | called by muse, mutect2
- MRPL10 | c.411T>C p.D137= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs1190300346, COSV50111204; called by muse, mutect2
- PADI2 | c.561G>A p.R187= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- PNMA2 | c.249G>A p.Q83= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- PRPF6 | c.534G>A p.K178= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- TAAR2 | c.534G>A p.V178= (on ENST00000367931 / NM_001033080.1; = p.V133= on NM_014626.3) | Silent (SNP) | VAF 11/189 reads (6%) | called by muse, mutect2
- TBC1D10C | c.1110G>A p.G370= | Silent (SNP) | VAF 16/464 reads (3%) | called by muse, mutect2
- TGM5 | c.1806G>A p.E602= (on ENST00000220420 / NM_201631.4; = p.E520= on NM_004245.4) | Silent (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 9/29 reads (31%) | catalogued as rs190105354; called by muse, varscan2
- BLACE | n.1630G>C | RNA (SNP) | VAF 16/322 reads (5%) | called by muse, mutect2
- CCDC69 | c.*96G>A | 3'UTR (SNP) | VAF 24/766 reads (3%) | called by muse, mutect2
- DUSP13 | c.*53C>T | 3'UTR (SNP) | VAF 23/402 reads (6%) | catalogued as rs1415956580; called by muse, mutect2
- FAM183BP | n.790C>T | RNA (SNP) | VAF 16/174 reads (9%) | catalogued as rs1029681882; called by muse, mutect2
- GBX2 | c.523+287G>T | Intron (SNP) | VAF 22/490 reads (4%) | catalogued as rs1274745971; called by muse, mutect2
- HERC2P3 | n.1334G>A | RNA (SNP) | VAF 30/754 reads (4%) | called by muse, mutect2
- NRBP2 | c.841-97G>A | Intron (SNP) | VAF 28/726 reads (4%) | called by muse, mutect2
- NRBP2 | c.841-98G>A | Intron (SNP) | VAF 28/736 reads (4%) | called by muse, mutect2
- RAB7A | c.399+23A>T | Intron (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- RORC | c.70+3462G>A | Intron (SNP) | VAF 13/339 reads (4%) | called by muse, mutect2
- SLC41A1 | c.*26C>T | 3'UTR (SNP) | VAF 17/294 reads (6%) | called by muse, mutect2
- SLC7A10 | c.1016+85G>A | Intron (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- SLC7A10 | c.1016+84G>A | Intron (SNP) | VAF 11/277 reads (4%) | catalogued as rs1256579338; called by muse, mutect2
- SPNS2 | c.*341C>T | 3'UTR (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- STAG3L2 | n.1023G>T | RNA (SNP) | VAF 22/311 reads (7%) | catalogued as rs1554426472; called by muse, mutect2
- UNC5D | c.*2584A>G | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ZNF99 | c.-15C>G | 5'UTR (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
